Gene-level copy-number profile of tumor specimen ALCH-B4ZQ-TTP1-A from ALCHEMIST case ALCH-B4ZQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,626 days).
Specimen ALCH-B4ZQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8ad7955d-fdd2-46ef-8906-cfcf3ee20526.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4ZQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/08cce33f-811d-44b7-a1c4-6dde2cc817d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 9,401; copy number 2: 45,182; copy number 3: 3,624; copy number 4: 106; copy number 5: 7; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,991,438–42,991,544, 1 gene: RNU6-880P.
- chr1:223,947,605–223,950,416, 1 gene: CICP5.
- chr2:238,100,340–238,133,287, 1 gene: ESPNL.
- chr5:1,877,413–1,900,493, 3 genes: IRX4, IRX4-AS1, CTD-2194D22.4.
- chr5:171,359,117–171,386,760, 5 genes: RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912.
- chr7:129,502,531–129,512,918, 1 gene: SMKR1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr10:67,874,332–67,874,911, 1 gene: RPL12P8.
- chr15:25,189,414–25,230,919, 21 genes (within-gene range 0–1): SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33.
- chr15:40,694,774–40,732,340, 1 gene (within-gene range 0–2): RAD51.
- chr15:64,701,248–64,825,668, 4 genes (within-gene range 0–1): AC100830.1, RBPMS2, MIR1272, PIF1.
- chr15:99,396,613–99,435,160, 3 genes: AC015660.2, AC015660.3, AC015660.1.
- chr19:39,196,964–39,204,263, 2 genes: NCCRP1, SYCN.
- chr21:8,701,461–8,761,335, 2 genes: CR381572.1, LINC01666.
- chr22:15,528,192–15,703,403, 14 genes: OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH-AS1, RNU6-816P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,874,793–144,068,350, 7 genes, copy number 5: FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr22:22,644,475–22,647,903, 1 gene, copy number 9: GGTLC2.

Autosomal genes at a single copy (total copy number 1): 9,291. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
